Somatic mutation profile of tumor specimen TCGA-CH-5748-01A (aliquot TCGA-CH-5748-01A-11D-1576-08) from TCGA case TCGA-CH-5748, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 64.7 years (23,649 days).
Specimen TCGA-CH-5748-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dd6bc7ec-691e-412b-bb01-9a1d4e3e31a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CH-5748-10A (Blood Derived Normal), aliquot TCGA-CH-5748-10A-01D-1576-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/671aff4f-98fc-4ce4-87dd-9d816323cee7

The open-access MAF lists 28 somatic variants for this specimen: 20 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 19, Silent 8, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MED12 | c.3670C>T p.L1224F | Missense Mutation (SNP) | VAF 8/48 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057519912, COSV61329632, COSV61332429; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CA14 | c.791G>C p.R264P | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52530039; called by muse, mutect2
- CRK | c.172T>G p.S58A | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56031568; called by muse, mutect2, varscan2
- DHRS7 | c.490T>G p.L164V | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.422); catalogued as COSV53666999; called by muse, mutect2
- ETFA | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.948); catalogued as COSV51211948; called by muse, mutect2
- FAM234A | c.275A>G p.Y92C | Missense Mutation (SNP) | VAF 25/430 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs922150511, COSV56996668; called by muse, mutect2
- GPR183 | c.65A>C p.D22A | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as COSV63119896; called by muse, mutect2
- NAV2 | c.1403C>G p.A468G (on ENST00000396087 / NM_001244963.2; = p.A445G on NM_145117.5) | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV62322824; called by muse, mutect2
- NEURL4 | c.3757T>C p.S1253P | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.086); catalogued as COSV59752002; called by muse, mutect2, varscan2
- PKD1 | c.12025G>A p.V4009M (on ENST00000262304 / NM_001009944.3; = p.V4008M on NM_000296.4) | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.937); catalogued as rs749740699, COSV51921361; called by muse, mutect2, varscan2
- PROZ | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as rs1312449752, COSV61439937; called by muse, mutect2
- RTL6 | c.598C>T p.R200* | Nonsense Mutation (SNP) | VAF 13/81 reads (16%) | catalogued as COSV57979955; called by muse, mutect2, varscan2
- SCARA5 | c.1153A>C p.S385R | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.053); catalogued as COSV57279269; called by muse, mutect2, varscan2
- SLC25A2 | c.572A>G p.Y191C | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782556287, COSV53404553; called by muse, mutect2
- SNX18 | c.1057A>T p.R353W | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV57991013; called by muse, mutect2, varscan2
- TCEAL6 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as rs1473915769, COSV65654109; called by muse, mutect2, varscan2
- TTC37 | c.1835G>C p.G612A | Missense Mutation (SNP) | VAF 19/166 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV62455891; called by muse, mutect2, varscan2
- TXLNA | c.970G>C p.D324H | Missense Mutation (SNP) | VAF 14/171 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65314551, COSV65314889; called by muse, mutect2
- ZNF781 | c.101A>T p.E34V | Missense Mutation (SNP) | VAF 24/334 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as COSV62202245; called by muse, mutect2
- ZNF658 | c.3029G>T p.R1010I | Missense Mutation (SNP) | VAF 35/230 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CWH43 | c.420T>C p.Y140= | Silent (SNP) | VAF 13/130 reads (10%) | catalogued as COSV56941528; called by muse, mutect2, varscan2
- EYS | c.51T>A p.S17= | Silent (SNP) | VAF 18/116 reads (16%) | catalogued as COSV100675603, COSV60994080; called by muse, mutect2, varscan2
- HNRNPLL | c.234C>G p.V78= | Silent (SNP) | VAF 17/148 reads (11%) | catalogued as COSV55368641; called by muse, mutect2, varscan2
- HTR1E | c.429C>A p.I143= | Silent (SNP) | VAF 14/102 reads (14%) | catalogued as COSV59509356, COSV59509739; called by muse, mutect2, varscan2
- NLE1 | c.1206G>A p.R402= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as COSV50102976; called by muse, mutect2
- RASSF2 | c.576C>T p.N192= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as rs1279140486, COSV65081756; called by muse, mutect2
- SH3TC1 | c.3174G>A p.G1058= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV55287244; called by muse, mutect2, varscan2
- TMEFF2 | c.189A>G p.E63= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as rs752563226, COSV55836631; called by muse, mutect2
